Somatic mutation profile of tumor specimen TCGA-29-A5NZ-01A (aliquot TCGA-29-A5NZ-01A-11D-A403-09) from TCGA case TCGA-29-A5NZ, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary serous cystadenocarcinoma; Tissue or organ of origin: Specified parts of peritoneum; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.1 years (24,161 days).
Specimen TCGA-29-A5NZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47e9f203-63ea-4a32-8d3b-8834aaa5ece2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-A5NZ-10A (Blood Derived Normal), aliquot TCGA-29-A5NZ-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74449771-c018-41d9-af6f-90b3de4a81fc

The open-access MAF lists 61 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 36, Silent 17, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 8/10 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ACADS | c.1045A>C p.K349Q | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99656710; called by muse, mutect2, varscan2
- ADAMTS19 | c.2700C>A p.H900Q | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99177887, COSV99180536; called by muse, mutect2, varscan2
- ARIH2 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100711309; called by muse, mutect2, varscan2
- BBX | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100361530; called by muse, mutect2, varscan2
- BOD1L1 | c.4501C>A p.Q1501K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99239321; called by muse, mutect2, varscan2
- CREB3L1 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.094); catalogued as COSV99915010; called by muse, mutect2
- DAAM2 | c.2317G>C p.A773P | Missense Mutation (SNP) | VAF 219/951 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV99225651; called by muse, mutect2, varscan2
- DPT | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1230836353, COSV100892137; called by muse, mutect2, varscan2
- FAM47C | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.996); catalogued as COSV63723806; called by muse, mutect2, varscan2
- FOXF2 | c.519C>A p.Y173* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV52525059, COSV99453232; called by muse, mutect2, varscan2
- GGN | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766551198, COSV99287464; called by muse, mutect2, varscan2
- GMPS | c.1888T>G p.S630A | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); catalogued as COSV99903136; called by muse, mutect2, varscan2
- GRIA4 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as rs754605807, COSV56921640; called by muse, varscan2
- JAG2 | c.1217G>A p.G406D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.812); catalogued as rs1486443143, COSV100078334; called by muse, mutect2, varscan2
- JAG2 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59310832; called by muse, mutect2, varscan2
- JAG2 | c.857G>A p.S286N | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs371109067; called by muse, mutect2, varscan2
- KIAA1549L | c.257C>G p.P86R (on ENST00000321505; = p.P383R on NM_012194.3) | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.029); catalogued as COSV55771986, COSV99683457; called by muse, mutect2, varscan2
- LRP1B | c.4034T>G p.I1345R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV67278051, COSV99069272; called by muse, mutect2, varscan2
- MAST2 | c.3576G>C p.E1192D | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100788090; called by muse, varscan2
- MEGF6 | c.730+1G>C p.X244_splice | Splice Site (SNP) | VAF 25/90 reads (28%) | catalogued as rs777038081, COSV99620287, COSV99621806; called by muse, mutect2, varscan2
- METTL22 | c.962C>A p.A321D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.184); catalogued as COSV99371690; called by muse, mutect2, varscan2
- MGAT4C | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs753847188, COSV59836851; called by muse, mutect2, varscan2
- MYO3A | c.4445G>T p.C1482F | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99779601; called by muse, mutect2, varscan2
- MYO9B | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101261536; called by muse, mutect2, varscan2
- NPR1 | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100903750; called by muse, mutect2, varscan2
- PARP14 | c.3929C>T p.S1310L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.348); catalogued as COSV101506278; called by muse, mutect2, varscan2
- PLA2G4C | c.440C>G p.T147S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs1305025105, COSV100843932; called by muse, mutect2, varscan2
- RAD54L | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | catalogued as rs1312637312, COSV58440322; called by muse, mutect2, varscan2
- RNF40 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.594); catalogued as rs761113554, COSV100222063; called by muse, mutect2, varscan2
- RPGRIP1 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99251009; called by muse, mutect2, varscan2
- RPUSD3 | c.127C>A p.H43N | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1225027236, COSV101094693; called by muse, mutect2, varscan2
- RTN4IP1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765799580, COSV100954181; called by muse, mutect2, varscan2
- RUBCN | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99583988; called by muse, mutect2, varscan2
- SH3PXD2A | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583371; called by muse, mutect2, varscan2
- SIKE1 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV99285264; called by muse, mutect2, varscan2
- SPRYD3 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as rs147084619; called by muse, mutect2, varscan2
- STK11IP | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99822805; called by muse, mutect2, varscan2
- TGM4 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs369266664; called by muse, mutect2, varscan2
- TRIR | c.183C>G p.N61K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99662215; called by muse, mutect2, varscan2
- ATXN2L | c.2293_2330del p.P765Sfs*253 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel
- GINS3 | c.306del p.D103Ifs*63 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel, varscan2
- IGKV1-39 | c.55+1G>A p.X19_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | called by mutect2, varscan2
- RBM27 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BOC | c.1086C>T p.P362= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99848679; called by muse, mutect2, varscan2
- CIC | c.627C>T p.I209= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99359543; called by mutect2, varscan2
- COBLL1 | c.2439G>A p.V813= (on ENST00000392717; = p.V775= on NM_014900.5) | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99527890; called by muse, mutect2, varscan2
- DICER1 | c.2136G>A p.L712= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV100602085; called by muse, mutect2, varscan2
- FBXL18 | c.1338C>T p.R446= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs759644160, COSV101212063; called by muse, mutect2, varscan2
- GASK1B | c.639C>G p.P213= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99647600; called by muse, mutect2, varscan2
- GCM1 | c.12C>T p.D4= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs779224988, COSV52524282; called by muse, mutect2, varscan2
- GRIK3 | c.474G>A p.S158= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs144754408; called by muse, mutect2, varscan2
- KIRREL2 | c.336C>T p.S112= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV52877070; called by muse, mutect2, varscan2
- MDN1 | c.15156C>T p.A5052= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs145493272; called by muse, mutect2, varscan2
- MYF6 | c.291C>T p.A97= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs1431214720, COSV57353048; called by muse, mutect2, varscan2
- MYO9A | c.5877G>A p.V1959= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100613468; called by muse, mutect2, varscan2
- OR10H2 | c.369C>T p.Y123= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1326124650, COSV59946427; called by muse, mutect2
- PCDHA12 | c.2016C>T p.N672= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs781785108, COSV56477226; called by muse, mutect2, varscan2
- PCDHB4 | c.1899C>T p.D633= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV52025688; called by muse, mutect2, varscan2
- SLC52A2 | c.861C>T p.N287= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs782362832, COSV57353899; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNR | c.3318G>A p.T1106= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as rs902113167, COSV99689490, COSV99690662; called by muse, mutect2, varscan2
